Somatic mutation profile of tumor specimen C3N-00388-01 (aliquot CPT0016940008) from CPTAC case C3N-00388, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.1 years (21,570 days).
Specimen C3N-00388-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a330352c-4e95-4018-8d1f-32d318458ecf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00388-71 (Blood Derived Normal), aliquot CPT0017290002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13770316-4388-4564-80d8-09dd984642d2

The open-access MAF lists 494 somatic variants for this specimen: 346 protein-altering or splice-affecting, 102 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 260, Silent 102, Frame Shift Del 54, Intron 24, Frame Shift Ins 12, Nonsense Mutation 9, 3'UTR 9, RNA 6, Splice Site 6, 5'Flank 5, Splice Region 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 34/105 reads (32%) | catalogued as rs774824767, CM103536; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.1113del p.Q372Sfs*19 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | catalogued as rs875989848; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 94/237 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.5854C>T p.R1952W | Missense Mutation (SNP) | VAF 90/205 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs886041219, CM052316, COSV61771898; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 43/116 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 305/380 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SNX14 | c.1132C>T p.R378* (on ENST00000314673 / NM_001350535.1; = p.R334* on NM_020468.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/80 reads (8%) | catalogued as rs786205229, CM154285; ClinVar: pathogenic; called by muse, mutect2
- AASS | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 116/331 reads (35%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.961); catalogued as rs868487258, COSV62790109; called by muse, mutect2, varscan2
- ACOX3 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as rs142830697; called by muse, mutect2, varscan2
- ADAM22 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99717796; called by muse, mutect2, varscan2
- ADM2 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 74/194 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs768717029, COSV99062670; called by muse, mutect2, varscan2
- AMER3 | c.1550C>T p.T517M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as rs757634081, COSV58469265; called by muse, mutect2
- AMIGO3 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 110/319 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1361515145, COSV100246593; called by muse, mutect2, varscan2
- ANKRD33B | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.207); catalogued as rs750557599, COSV56982003; called by muse, mutect2, varscan2
- ARHGEF40 | c.2209del p.A737Pfs*3 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | catalogued as rs749402223; called by mutect2, varscan2
- ARPC2 | c.544A>G p.M182V | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV55286821; called by muse, mutect2
- ATG101 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs1411711963; called by muse, mutect2
- BARHL2 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs574470412; called by muse, mutect2
- BEND3 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 109/258 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.09); catalogued as rs782731122, COSV64681450; called by muse, mutect2, varscan2
- C1orf112 | c.756del p.F252Lfs*51 | Frame Shift Del (DEL) | VAF 38/138 reads (28%) | catalogued as rs1558068270; called by mutect2, pindel, varscan2
- CADM4 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as rs1281965411, COSV55928088; called by muse, mutect2
- CAPN12 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 130/376 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs775825228; called by muse, mutect2, varscan2
- CASP5 | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.146); catalogued as rs1358811356; called by muse, mutect2, varscan2
- CAVIN2 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.019); catalogued as rs1191492992; called by muse, mutect2, varscan2
- CCDC141 | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs1471510758, COSV99837044; called by muse, mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 32/106 reads (30%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC88B | c.1025G>C p.R342P | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1459038221; called by muse, mutect2, varscan2
- CCDC88C | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 84/241 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs749773290; called by muse, mutect2, varscan2
- CDH2 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as rs1228174771; called by muse, mutect2, varscan2
- CENPS-CORT | c.335_337del p.W112del | In Frame Del (DEL) | VAF 54/156 reads (35%) | catalogued as rs1323900808; called by pindel, varscan2
- CEP128 | c.947T>G p.L316R | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV53676660; called by muse, mutect2
- CERS4 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.69); catalogued as rs776877996; called by muse, mutect2, varscan2
- CERT1 | c.264del p.T89Hfs*85 | Frame Shift Del (DEL) | VAF 16/131 reads (12%) | catalogued as rs893362976; called by mutect2, pindel, varscan2
- CFAP69 | c.1726A>G p.S576G | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as rs1429613387; called by muse, mutect2
- CNTNAP5 | c.572A>G p.Y191C | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV101443119; called by muse, mutect2
- COL6A2 | c.208A>G p.M70V | Missense Mutation (SNP) | VAF 144/371 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as rs1006510673; called by muse, mutect2, varscan2
- CREB3L2 | c.785G>A p.G262D | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57793527; called by muse, mutect2, varscan2
- CSMD2 | c.9604G>A p.G3202R | Missense Mutation (SNP) | VAF 98/236 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.047); catalogued as rs779044426, COSV53898224, COSV53926649; called by muse, mutect2, varscan2
- CYB561 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs763576870, COSV62539410; called by muse, mutect2, varscan2
- DDX10 | c.238del p.T80Hfs*2 | Frame Shift Del (DEL) | VAF 10/130 reads (8%) | catalogued as rs1176416201; called by mutect2, pindel
- DHX34 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs550371648, COSV60898025; called by muse, mutect2, varscan2
- DHX9 | c.2746G>A p.V916I | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.832); catalogued as rs1302395270, COSV62362167; called by muse, mutect2, varscan2
- DISP3 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53825872, COSV99609367; called by muse, mutect2, varscan2
- DNAH12 | c.9247G>A p.G3083R (on ENST00000351747; = p.G3951R on NM_001366028.2) | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1485135870; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- EAF2 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.383); catalogued as rs138459007; called by muse, mutect2
- ERBB3 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 26/458 reads (6%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.925); catalogued as rs143770796, COSV99031581; called by muse, mutect2
- EVX2 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.185); catalogued as rs1011864573, COSV57964493; called by muse, mutect2, varscan2
- EXOC3L1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1199562563, COSV52047390; called by muse, mutect2, varscan2
- FAM107B | c.-122-5del | Splice Region (DEL) | VAF 24/46 reads (52%) | catalogued as rs756478120; called by mutect2, varscan2
- FAT3 | c.919del p.D307Ifs*3 | Frame Shift Del (DEL) | VAF 42/119 reads (35%) | catalogued as COSV53142296; called by mutect2, pindel, varscan2
- FCN3 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1196817722; called by muse, mutect2, varscan2
- FGB | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV57417990; called by muse, mutect2, varscan2
- FIGNL2 | c.1892G>A p.G631D | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.462); catalogued as rs754733766; called by muse, mutect2, varscan2
- FLCN | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 32/404 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs1223326792; called by muse, mutect2
- FNBP1L | c.219T>A p.F73L | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs766939416, COSV53096948; called by muse, mutect2, varscan2
- FNDC1 | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs763422899; called by muse, mutect2, varscan2
- FRMD7 | c.1492del p.Y498Mfs*26 | Frame Shift Del (DEL) | VAF 16/186 reads (9%) | catalogued as CD087853, CD118788; called by mutect2, pindel
- FTSJ1 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 26/397 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs149550806; ClinVar: likely benign; called by muse, mutect2
- FUT4 | c.741del p.D248Tfs*48 | Frame Shift Del (DEL) | VAF 84/242 reads (35%) | catalogued as rs746338726; called by mutect2, pindel, varscan2
- FZR1 | c.1042G>A p.V348M | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as rs762426128, COSV58052685; called by muse, mutect2, varscan2
- GABRA5 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.315); catalogued as rs1278476538, COSV59475638; called by muse, mutect2
- GCNA | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 168/460 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as rs947249334, COSV65468364; called by muse, mutect2, varscan2
- GFOD1 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.044); catalogued as rs759860102, COSV64955200; called by muse, mutect2, varscan2
- GJB1 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 100/238 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as rs1426533412; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLA | c.170A>G p.Q57R | Missense Mutation (SNP) | VAF 42/518 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.054); catalogued as rs869312260, CX0911225; called by muse, mutect2
- GPR15 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs762768983, COSV52521299; called by muse, mutect2, varscan2
- HARBI1 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.339); catalogued as rs1170516786, COSV56319089; called by muse, mutect2
- HDAC9 | c.1392T>G p.I464M | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.854); catalogued as COSV67784330; called by muse, mutect2
- HNF1A | c.1136del p.P379Lfs*5 | Frame Shift Del (DEL) | VAF 49/177 reads (28%) | catalogued as COSV57466638; called by mutect2, pindel, varscan2
- HNRNPH1 | c.1057+1G>A p.X353_splice | Splice Site (SNP) | VAF 10/107 reads (9%) | catalogued as rs1428621942; called by muse, mutect2
- HYDIN | c.14102G>A p.R4701H | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs371498063, COSV101124976; called by mutect2, varscan2
- IL17B | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764889728; called by muse, mutect2, varscan2
- IL7R | c.374C>A p.T125N | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV57407319; called by muse, mutect2
- INTS1 | c.1768G>A p.V590I | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs902584801; called by muse, mutect2
- KCTD10 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.166); catalogued as rs1434330317, COSV57326715; called by muse, mutect2
- KMT2B | c.4858G>T p.E1620* | Nonsense Mutation (SNP) | VAF 89/240 reads (37%) | catalogued as COSV55858017, COSV99719529; called by muse, mutect2, varscan2
- LIMK1 | c.1139C>T p.T380M | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs782494881, COSV60280324; called by muse, mutect2
- LIPC | c.177T>G p.N59K | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as rs751257289; called by muse, mutect2
- LPIN2 | c.698+1G>A p.X233_splice | Splice Site (SNP) | VAF 50/123 reads (41%) | catalogued as rs1449758984, COSV55240771; called by muse, mutect2, varscan2
- LRWD1 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as rs986641243; called by muse, mutect2
- MACF1 | c.22027G>A p.D7343N (on ENST00000372915; = p.D5388N on NM_012090.5) | Missense Mutation (SNP) | VAF 86/250 reads (34%) | catalogued as rs1263871195; called by muse, mutect2, varscan2
- MAEL | c.827A>G p.D276G | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1184791510; called by muse, mutect2
- MAGEL2 | c.290del p.G97Afs*12 | Frame Shift Del (DEL) | VAF 43/112 reads (38%) | catalogued as rs1401986830; called by mutect2, pindel, varscan2
- MAPKAPK3 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs759497061, COSV100781800, COSV63596839; called by muse, mutect2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 22/126 reads (17%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MKKS | c.1648C>T p.Q550* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as CM102564; called by muse, mutect2
- MNDA | c.216G>A p.M72I | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100933256, COSV63741864; called by muse, mutect2, varscan2
- MSH4 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); catalogued as rs1487084517, COSV99592208; called by muse, mutect2
- MTUS2 | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 80/240 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV70917564; called by muse, varscan2
- MUC12 | c.13274C>A p.T4425N (on ENST00000379442; = p.T4282N on NM_001164462.1) | Missense Mutation (SNP) | VAF 110/318 reads (35%) | SIFT deleterious (0.04); catalogued as rs1217180450; called by muse, mutect2, varscan2
- NACAD | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs1562928867; called by muse, mutect2, varscan2
- NCAPD2 | c.2647G>A p.E883K | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs762710261, COSV59703459; ClinVar: uncertain significance; called by muse, mutect2
- NCCRP1 | c.687+1G>A p.X229_splice | Splice Site (SNP) | VAF 34/85 reads (40%) | catalogued as rs757801641; called by muse, mutect2, varscan2
- NCLN | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs539036309; called by muse, mutect2, varscan2
- NCLN | c.658G>C p.V220L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as rs1379716154, COSV55743388; called by muse, mutect2, varscan2
- NDUFB8 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.895); catalogued as rs1239013578, COSV100144043; called by muse, mutect2, varscan2
- NLRC3 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as rs373362956; called by muse, mutect2, varscan2
- NR0B1 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 94/205 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs779434195; called by muse, mutect2, varscan2
- NUCB1 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs149685717; called by muse, mutect2
- NUP210L | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1336301673; called by muse, mutect2, varscan2
- OR52W1 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV60951418; called by muse, mutect2
- PAPPA | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs199822574, COSV60284182, COSV60284455; called by muse, mutect2, varscan2
- PCLO | c.12271G>A p.V4091M | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs766076530; called by muse, mutect2, varscan2
- PHLDB1 | c.2197C>T p.R733C | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs141282851; called by muse, mutect2
- PKM | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 37/409 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as rs763255904; called by muse, mutect2
- PLA2G4F | c.560G>A p.G187D | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs1254474563; called by muse, mutect2, varscan2
- PNPLA4 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749415144; called by muse, mutect2, varscan2
- PSD4 | c.1797G>T p.E599D | Missense Mutation (SNP) | VAF 87/214 reads (41%) | SIFT tolerated (0.92); PolyPhen benign (0.013); catalogued as COSV55528330; called by muse, mutect2, varscan2
- PSMD12 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.381); catalogued as rs1422925980; called by muse, mutect2
- PTPRZ1 | c.2840C>T p.A947V | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV101101084; called by muse, mutect2
- RAPGEF4 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs200268023, COSV51381163, COSV51403468; called by muse, mutect2
- RASGEF1C | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.071); catalogued as rs774289825; called by muse, mutect2, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 41/118 reads (35%) | catalogued as COSV56484832; called by mutect2, varscan2
- RHBDF2 | c.1389G>A p.S463= | Splice Region (SNP) | VAF 9/108 reads (8%) | catalogued as rs1355598816, COSV99166186; called by muse, mutect2
- RNASEL | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1410720560; called by muse, mutect2
- ROCK2 | c.2921C>T p.T974I | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1423756088; called by muse, mutect2, varscan2
- RRAGA | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 70/143 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1309038735; called by muse, mutect2, varscan2
- RUNDC3B | c.134A>G p.K45R | Missense Mutation (SNP) | VAF 11/261 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99712675; called by muse, mutect2
- SAGE1 | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.329); catalogued as rs782681413, COSV61016346; called by muse, mutect2
- SEMA4A | c.992G>A p.G331D | Missense Mutation (SNP) | VAF 20/396 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs1338290762; called by muse, mutect2
- SEMA5A | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753154714, COSV66790248; called by muse, mutect2, varscan2
- SH3TC2 | c.2534C>T p.A845V | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as rs757053201; called by muse, mutect2, varscan2
- SHANK3 | c.2191G>T p.A731S | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.883); catalogued as COSV53189566; called by muse, mutect2, varscan2
- SHPK | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as rs1020355454; called by muse, mutect2, varscan2
- SHROOM3 | c.3110C>T p.P1037L | Missense Mutation (SNP) | VAF 26/448 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs1410428592; called by muse, mutect2
- SLC16A14 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV54618202; called by muse, mutect2, varscan2
- SLC22A6 | c.777del p.F259Lfs*27 | Frame Shift Del (DEL) | VAF 41/111 reads (37%) | catalogued as rs749849908; called by mutect2, pindel, varscan2
- SLC26A3 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 134/336 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.514); catalogued as rs747100587, COSV60639904; called by muse, mutect2, varscan2
- SLC38A9 | c.1113del p.F371Lfs*10 | Frame Shift Del (DEL) | VAF 39/145 reads (27%) | catalogued as rs746769804; called by mutect2, pindel, varscan2
- SLC9A3 | c.2199del p.I734Sfs*68 | Frame Shift Del (DEL) | VAF 62/166 reads (37%) | catalogued as rs1193005485; called by mutect2, pindel, varscan2
- SPATA31D1 | c.3889G>A p.V1297M | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100782454; called by muse, mutect2, varscan2
- SPATA31E1 | c.2266C>A p.P756T | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.637); catalogued as COSV100350626; called by muse, mutect2, varscan2
- SPEG | c.2043del p.W683Gfs*37 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs1236031589; called by mutect2, pindel, varscan2
- SUGT1 | c.1091del p.K364Sfs*4 (on ENST00000343788 / NM_001130912.3; = p.K332Sfs*4 on NM_006704.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 23/62 reads (37%) | catalogued as COSV59421975; called by mutect2, pindel, varscan2
- TAF6L | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 82/209 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1389961060, COSV53667917; called by muse, mutect2, varscan2
- TEFM | c.727_728del p.L243Vfs*20 | Frame Shift Del (DEL) | VAF 23/87 reads (26%) | catalogued as rs760087934; called by pindel, varscan2
- TGFBI | c.1502del p.P501Qfs*9 | Frame Shift Del (DEL) | VAF 34/129 reads (26%) | catalogued as rs771515402; called by mutect2, varscan2
- THOC2 | c.1664G>A p.R555H | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as COSV99833316; called by muse, mutect2, varscan2
- TMEM41A | c.467dup p.L158Ifs*40 | Frame Shift Ins (INS) | VAF 18/49 reads (37%) | catalogued as rs758476632; called by mutect2, varscan2
- TOP2A | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs771864534; called by muse, mutect2, varscan2
- TRAF7 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs745441816, COSV58214574; called by muse, mutect2, varscan2
- TRIM15 | c.1091C>T p.T364M | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs769486281; called by muse, mutect2, varscan2
- TRIM7 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51247905; called by muse, mutect2
- TXNRD1 | c.316G>T p.A106S (on ENST00000525566 / NM_001093771.3; = p.A8S on NM_003330.4) | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs768084670; called by muse, mutect2, varscan2
- UNC13B | c.2113G>A p.V705I | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs138199360; called by muse, mutect2
- USP8 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs376376613; called by muse, mutect2, varscan2
- VAV1 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 73/203 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs774093642; called by muse, mutect2, varscan2
- WDR97 | c.3783del p.S1262Afs*11 | Frame Shift Del (DEL) | VAF 8/99 reads (8%) | catalogued as rs548083057; called by mutect2, pindel
- ZBTB4 | c.1678C>T p.R560W | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs1161112700, COSV60978503; called by muse, mutect2, varscan2
- ZHX2 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763906432, COSV58710698; called by muse, mutect2, varscan2
- ZNF287 | c.1128del p.K376Nfs*9 | Frame Shift Del (DEL) | VAF 12/155 reads (8%) | catalogued as COSV67688298; called by mutect2, pindel
- ZNF319 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.034); catalogued as COSV99539903; called by muse, mutect2, varscan2
- ZNF527 | c.1007A>G p.N336S | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as rs1320483904, COSV100648685; called by muse, mutect2, varscan2
- ZNF835 | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.539); catalogued as rs1398663390, COSV101606301; called by muse, mutect2, varscan2
- ZNF91 | c.2248G>A p.A750T | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.693); catalogued as rs552396941; called by muse, mutect2, varscan2
- ABCG4 | c.1291A>G p.M431V | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ACTN2 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 115/296 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- ADAMTSL2 | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 141/348 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ADCY9 | c.1349G>T p.G450V | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADCYAP1 | c.210del p.A71Pfs*88 | Frame Shift Del (DEL) | VAF 9/120 reads (8%) | called by mutect2, pindel
- ADGRD1 | c.2477T>C p.L826P | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- ADGRF2 | c.404G>A p.C135Y (on ENST00000296862 / NM_001368115.2; = p.C67Y on NM_153839.7) | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRG1 | c.1208T>C p.L403P | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADRA2B | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- AGBL5 | c.1628del p.P543Rfs*52 | Frame Shift Del (DEL) | VAF 50/147 reads (34%) | called by mutect2, pindel, varscan2
- AKR7A2 | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 115/295 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ALPK3 | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 13/201 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANKRD18A | c.844dup p.R282Kfs*26 | Frame Shift Ins (INS) | VAF 41/124 reads (33%) | called by mutect2, varscan2
- ANO8 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- ARHGEF2 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 9/201 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ARID4B | c.2815del p.T939Rfs*2 | Frame Shift Del (DEL) | VAF 83/257 reads (32%) | called by mutect2, pindel, varscan2
- ART4 | c.928del p.S310Pfs*19 | Frame Shift Del (DEL) | VAF 73/212 reads (34%) | called by mutect2, pindel, varscan2
- ASCC3 | c.2570A>G p.Q857R | Missense Mutation (SNP) | VAF 34/328 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATRX | c.423del p.F141Lfs*12 | Frame Shift Del (DEL) | VAF 30/349 reads (9%) | called by mutect2, pindel
- B3GNT5 | c.36del p.K12Nfs*4 | Frame Shift Del (DEL) | VAF 24/58 reads (41%) | called by mutect2, pindel, varscan2
- B4GALNT3 | c.1679A>G p.Q560R | Missense Mutation (SNP) | VAF 23/314 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2
- BAHCC1 | c.983del p.P328Rfs*60 | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | called by mutect2, pindel, varscan2
- BICRA | c.2632del p.H878Tfs*69 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- BRS3 | c.980C>A p.P327H | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRSK2 | c.1854del p.S619Afs*16 | Frame Shift Del (DEL) | VAF 55/127 reads (43%) | called by mutect2, pindel, varscan2
- C1orf131 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- C1orf52 | c.43T>C p.Y15H | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- C6orf58 | c.991T>C p.*331Rext*3 | Nonstop Mutation (SNP) | VAF 29/54 reads (54%) | called by muse, mutect2, varscan2
- C9orf153 | c.613T>C p.W205R | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- CAPZA3 | c.416A>T p.N139I | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by muse, mutect2
- CARD9 | c.1343A>C p.Q448P | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- CDCA5 | c.584C>A p.P195H | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- CDK12 | c.907A>G p.S303G | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.97); called by muse, mutect2
- CEP85 | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT tolerated (0.94); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CFAP43 | c.1007T>C p.M336T | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRM4 | c.529A>G p.K177E | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CHRNB2 | c.1155C>A p.D385E | Missense Mutation (SNP) | VAF 176/452 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CHRNB2 | c.1225C>A p.P409T | Missense Mutation (SNP) | VAF 92/279 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNNM4 | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.468); called by muse, mutect2
- CNTNAP4 | c.1730A>T p.N577I | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- COL11A1 | c.780+2T>C p.X260_splice | Splice Site (SNP) | VAF 86/237 reads (36%) | called by muse, mutect2, varscan2
- COLQ | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2
- CPT1A | c.1391del p.N464Tfs*67 | Frame Shift Del (DEL) | VAF 157/429 reads (37%) | called by mutect2, pindel, varscan2
- CSDE1 | c.973C>T p.R325C (on ENST00000358528 / NM_001007553.3; = p.R294C on NM_007158.6) | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- CSMD1 | c.9224C>T p.S3075F (on ENST00000520002; = p.S3074F on NM_033225.6) | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.266); called by muse, mutect2
- CTSW | c.493C>A p.L165M | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- CUL7 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 17/445 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- CYLC1 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- DLC1 | c.445A>G p.K149E | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF3M | c.482dup p.H162Afs*9 | Frame Shift Ins (INS) | VAF 42/137 reads (31%) | called by mutect2, varscan2
- EML3 | c.1623G>A p.W541* | Nonsense Mutation (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- EP400 | c.8857G>A p.A2953T | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- EPS8L2 | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- EXOC3L1 | c.413C>A p.P138H | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM43B | c.911dup p.A305Rfs*81 | Frame Shift Ins (INS) | VAF 41/140 reads (29%) | called by mutect2, pindel, varscan2
- FAM50A | c.69G>T p.K23N | Missense Mutation (SNP) | VAF 19/264 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.282); called by muse, mutect2
- FAT2 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.115); called by muse, mutect2
- FOXP2 | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2
- FOXR2 | c.714C>A p.S238R | Missense Mutation (SNP) | VAF 85/264 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- FRRS1 | c.1053del p.K351Nfs*4 | Frame Shift Del (DEL) | VAF 28/221 reads (13%) | called by mutect2, pindel, varscan2
- FYB1 | c.972del p.P325Hfs*44 | Frame Shift Del (DEL) | VAF 57/125 reads (46%) | called by mutect2, varscan2
- GALM | c.538A>G p.N180D | Missense Mutation (SNP) | VAF 101/241 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GATA1 | c.1174G>T p.G392C | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- GLRA1 | c.131A>C p.K44T | Missense Mutation (SNP) | VAF 25/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR158 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.047); called by muse, mutect2
- GPR3 | c.827C>A p.P276H | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); called by muse, mutect2
- GRAP2 | c.17A>G p.K6R | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GSDMD | c.142T>C p.W48R | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.077); called by muse, mutect2
- GTF3C2 | c.2095T>C p.Y699H | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- HAS1 | c.1228C>A p.L410M | Missense Mutation (SNP) | VAF 138/356 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- HEMK1 | c.50G>T p.R17M | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- HERC2 | c.8306G>A p.R2769H | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.154); called by muse, mutect2
- HEXA | c.253+2T>C p.X85_splice | Splice Site (SNP) | VAF 41/117 reads (35%) | called by muse, mutect2, varscan2
- HMGCS2 | c.904A>G p.T302A | Missense Mutation (SNP) | VAF 17/316 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.01); called by muse, mutect2
- HOXC6 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- HSD11B2 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- IFIH1 | c.2381A>G p.E794G | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFNAR2 | c.173del p.N58Tfs*16 | Frame Shift Del (DEL) | VAF 52/206 reads (25%) | called by pindel, varscan2
- IGSF9 | c.338T>G p.L113R | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2
- IL22RA2 | c.641del p.K214Rfs*18 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | called by pindel, varscan2
- ILDR2 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.158); called by muse, mutect2
- INPP5A | c.939G>T p.K313N | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- INPPL1 | c.2040+2T>C p.X680_splice | Splice Site (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- IPO4 | c.407_408dup p.M137Rfs*7 | Frame Shift Ins (INS) | VAF 25/89 reads (28%) | called by mutect2, varscan2
- IRS4 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 177/466 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JAKMIP2 | c.377G>C p.S126T | Missense Mutation (SNP) | VAF 17/296 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.047); called by muse, mutect2
- JMJD1C | c.6698C>T p.A2233V | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.118); called by muse, mutect2
- KANSL1L | c.68A>T p.E23V | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNC4 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- KCTD13 | c.203C>A p.A68D | Missense Mutation (SNP) | VAF 159/420 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- KIAA0825 | c.752T>G p.L251* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- KIF26B | c.5503del p.A1835Pfs*41 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | called by mutect2, pindel, varscan2
- KLF3 | c.318dup p.Y107Ifs*72 | Frame Shift Ins (INS) | VAF 72/232 reads (31%) | called by mutect2, varscan2
- L1CAM | c.3722A>G p.N1241S | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LAP3 | c.1172C>T p.T391I | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LIFR | c.613T>C p.W205R | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMOD2 | c.166A>G p.T56A | Missense Mutation (SNP) | VAF 90/231 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LPA | c.4271C>T p.P1424L | Missense Mutation (SNP) | VAF 13/252 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- LRPPRC | c.2276C>G p.A759G | Missense Mutation (SNP) | VAF 87/227 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRN3 | c.509A>G p.H170R | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGED2 | c.1087A>T p.T363S | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.18); called by muse, mutect2
- MAP3K14 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- MAP3K4 | c.4334A>C p.K1445T | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- MED23 | c.3046C>A p.L1016M | Missense Mutation (SNP) | VAF 98/251 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MID2 | c.965G>A p.C322Y | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); called by muse, varscan2
- MMP9 | c.1712T>C p.F571S | Missense Mutation (SNP) | VAF 76/204 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPP7 | c.362C>A p.P121Q | Missense Mutation (SNP) | VAF 15/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MT1H | c.154G>C p.G52R | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- MVB12B | c.88T>C p.S30P | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2
- MX1 | c.1354A>G p.R452G | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); called by muse, mutect2
- MZF1 | c.1135A>G p.T379A | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); called by muse, mutect2
- NAPSA | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NEFH | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 63/364 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NLRP8 | c.122T>C p.V41A | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); called by muse, mutect2
- NOX1 | c.633del p.F211Lfs*8 | Frame Shift Del (DEL) | VAF 8/87 reads (9%) | called by mutect2, pindel, varscan2
- NPRL3 | c.259A>G p.K87E | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NSD1 | c.4455del p.V1486* | Frame Shift Del (DEL) | VAF 111/328 reads (34%) | called by mutect2, pindel, varscan2
- NUP42 | c.580del p.S194Vfs*2 | Frame Shift Del (DEL) | VAF 26/208 reads (13%) | called by pindel, varscan2
- NXT1 | c.251C>A p.A84D | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR4D9 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PADI4 | c.421T>C p.W141R | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PAK3 | c.1333G>A p.A445T (on ENST00000262836 / NM_001324328.2; = p.A430T on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHA12 | c.1846G>A p.V616I | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.21); called by muse, mutect2
- PCDHA3 | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- PCDHGA7 | c.560A>G p.D187G | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.208); called by muse, mutect2
- PCSK5 | c.2027del p.P676Lfs*38 | Frame Shift Del (DEL) | VAF 40/86 reads (47%) | called by mutect2, pindel, varscan2
- PCSK9 | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 119/302 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- PFAS | c.1843del p.D615Mfs*45 | Frame Shift Del (DEL) | VAF 28/85 reads (33%) | called by mutect2, pindel, varscan2
- PLA2G3 | c.476G>A p.C159Y | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHF1 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POMGNT2 | c.1397A>C p.K466T | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.19); called by muse, mutect2
- PPM1D | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRDM12 | c.41A>G p.K14R | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2
- PRDM6 | c.69G>A p.W23* | Nonsense Mutation (SNP) | VAF 14/294 reads (5%) | called by muse, mutect2
- PREP | c.1107C>G p.Y369* (on ENST00000369110; = p.Y435* on NM_002726.5) | Nonsense Mutation (SNP) | VAF 9/146 reads (6%) | called by muse, mutect2
- PRICKLE3 | c.1754T>C p.M585T | Missense Mutation (SNP) | VAF 99/248 reads (40%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRPF31 | c.1352G>A p.S451N | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PTEN | c.233C>G p.T78S | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTPN4 | c.2048dup p.N683Kfs*2 | Frame Shift Ins (INS) | VAF 24/109 reads (22%) | called by mutect2, pindel, varscan2
- RAD9A | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAI1 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 14/336 reads (4%) | called by muse, mutect2
- RAPGEF2 | c.2932A>G p.K978E | Missense Mutation (SNP) | VAF 119/308 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- RBM12 | c.1745G>T p.G582V | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBM47 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 97/249 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- REEP6 | c.194A>G p.Y65C | Missense Mutation (SNP) | VAF 13/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RETSAT | c.884del p.G295Vfs*12 | Frame Shift Del (DEL) | VAF 156/469 reads (33%) | called by mutect2, pindel, varscan2
- RFC4 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RNF126 | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- RNF32 | c.360dup p.G121Rfs*11 | Frame Shift Ins (INS) | VAF 61/190 reads (32%) | called by mutect2, pindel, varscan2
- RPS5 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- RRP1B | c.429G>T p.K143N | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2
- SCAF4 | c.2117dup p.P707Tfs*67 | Frame Shift Ins (INS) | VAF 42/110 reads (38%) | called by mutect2, pindel, varscan2
- SETD1B | c.3815_3816insTC p.G1273Qfs*3 | Frame Shift Ins (INS) | VAF 80/263 reads (30%) | called by mutect2, pindel, varscan2
- SH3GL3 | c.160del p.T54Pfs*15 | Frame Shift Del (DEL) | VAF 69/190 reads (36%) | called by mutect2, pindel, varscan2
- SH3KBP1 | c.1720dup p.L574Pfs*62 | Frame Shift Ins (INS) | VAF 30/111 reads (27%) | called by mutect2, pindel, varscan2
- SHPRH | c.3293A>G p.E1098G (on ENST00000275233 / NM_001042683.3; = p.E1107G on NM_173082.3) | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SNTG1 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 17/246 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2
- SPARCL1 | c.811A>G p.N271D | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- SPATA3 | c.89del p.Q30Rfs*62 | Frame Shift Del (DEL) | VAF 98/279 reads (35%) | called by mutect2, varscan2*
- SPIB | c.353del p.P118Rfs*62 | Frame Shift Del (DEL) | VAF 8/100 reads (8%) | called by mutect2, pindel
- ST3GAL5 | c.668C>T p.A223V (on ENST00000377332; = p.A263V on NM_003896.4) | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- STIM2 | c.742dup p.M248Nfs*23 | Frame Shift Ins (INS) | VAF 12/112 reads (11%) | called by mutect2, pindel
- SYNE1 | c.14612C>T p.A4871V (on ENST00000367255 / NM_182961.4; = p.A4800V on NM_033071.3) | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SZT2 | c.7208C>T p.T2403I (on ENST00000634258 / NM_001365999.1; = p.T2346I on NM_015284.4) | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TBC1D10A | c.518del p.G173Afs*11 | Frame Shift Del (DEL) | VAF 72/210 reads (34%) | called by mutect2, varscan2
- TMEM50A | c.2del p.M1? | Frame Shift Del (DEL) | VAF 39/116 reads (34%) | called by mutect2, pindel, varscan2
- TNFRSF4 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.043); called by muse, mutect2
- TRIM60 | c.969del p.K323Nfs*18 | Frame Shift Del (DEL) | VAF 25/91 reads (27%) | called by mutect2, pindel, varscan2
- TRIOBP | c.2638C>T p.P880S | Missense Mutation (SNP) | VAF 28/644 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); called by muse, mutect2
- TRPM2 | c.4265T>C p.M1422T | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- UBAC1 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.115); called by muse, mutect2
- UCK2 | c.35A>G p.H12R | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- USP34 | c.10064G>A p.R3355Q | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.885); called by muse, varscan2
- VGLL2 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- VWC2 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWF | c.8171G>A p.C2724Y | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- WAS | c.1367T>C p.L456P | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2
- WASHC2C | c.3459G>T p.K1153N (on ENST00000336378; = p.K1132N on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 275/725 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- WDR5 | c.648del p.V217Cfs*4 | Frame Shift Del (DEL) | VAF 46/133 reads (35%) | called by mutect2, varscan2
- WNT9B | c.29C>A p.P10H | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.484); called by muse, mutect2
- ZBTB7B | c.98T>C p.L33P (on ENST00000292176; = p.L67P on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZDHHC22 | c.748A>G p.M250V | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- ZEB1 | c.1880del p.K627Sfs*26 | Frame Shift Del (DEL) | VAF 43/508 reads (8%) | called by mutect2, pindel
- ZER1 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 105/275 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- ZNF24 | c.199C>A p.R67S | Missense Mutation (SNP) | VAF 90/230 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZNF277 | c.77del p.G26Vfs*2 | Frame Shift Del (DEL) | VAF 50/162 reads (31%) | called by mutect2, pindel, varscan2
- ZNF44 | c.673del p.T225Pfs*13 (on ENST00000356109 / NM_001164276.2; = p.T177Pfs*13 on NM_016264.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 15/115 reads (13%) | called by mutect2, pindel, varscan2
- ZNF474 | c.453G>T p.Q151H | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ZNF774 | c.1180C>A p.Q394K | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- ZNF99 | c.815T>C p.L272P | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ADAMTS2 | c.381C>T p.N127= | Silent (SNP) | VAF 48/156 reads (31%) | called by muse, mutect2, varscan2
- AHCTF1 | c.5529G>A p.T1843= (on ENST00000366508; = p.T1817= on NM_015446.5) | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as rs1258541803; called by muse, mutect2, varscan2
- CACNA2D1 | c.2631G>A p.E877= (on ENST00000356253 / NM_001366867.1; = p.E865= on NM_000722.4) | Silent (SNP) | VAF 37/91 reads (41%) | called by muse, mutect2, varscan2
- CBX7 | c.555G>A p.A185= | Silent (SNP) | VAF 71/184 reads (39%) | catalogued as rs765884458, COSV53358864; called by muse, mutect2, varscan2
- CCDC168 | c.13527A>G p.V4509= | Silent (SNP) | VAF 48/143 reads (34%) | called by muse, mutect2, varscan2
- CCDC89 | c.475C>T p.L159= | Silent (SNP) | VAF 14/174 reads (8%) | called by muse, mutect2
- CD200R1 | c.303T>C p.T101= (on ENST00000471858 / NM_170780.3; = p.T124= on NM_138806.4) | Silent (SNP) | VAF 25/326 reads (8%) | called by muse, mutect2
- CDC37 | c.501C>T p.R167= | Silent (SNP) | VAF 10/211 reads (5%) | called by muse, mutect2
- CEP112 | c.843T>G p.A281= | Silent (SNP) | VAF 8/117 reads (7%) | called by muse, mutect2
- CERS2 | c.129G>A p.L43= | Silent (SNP) | VAF 11/159 reads (7%) | called by muse, mutect2
- CNKSR1 | c.903G>A p.P301= (on ENST00000374253 / NM_001297647.2; = p.P294= on NM_006314.3) | Silent (SNP) | VAF 47/131 reads (36%) | catalogued as rs530262613; called by muse, mutect2, varscan2
- CNR1 | c.1162C>T p.L388= | Silent (SNP) | VAF 13/190 reads (7%) | called by muse, mutect2
- COL2A1 | c.279C>T p.L93= | Silent (SNP) | VAF 116/307 reads (38%) | catalogued as rs774746221, COSV61529453; called by muse, mutect2, varscan2
- CYP2D7 | c.1404C>T p.R468= | Silent (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
- CYSRT1 | c.474C>T p.C158= (on ENST00000409414; = p.C118= on NM_199001.5) | Silent (SNP) | VAF 76/205 reads (37%) | called by muse, mutect2, varscan2
- DCHS1 | c.4638C>T p.F1546= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as rs776657618, COSV55039522; called by muse, mutect2, varscan2
- DLGAP2 | c.1467C>T p.S489= | Silent (SNP) | VAF 78/155 reads (50%) | catalogued as rs201567259; called by muse, mutect2, varscan2
- DMD | c.7452C>T p.D2484= | Silent (SNP) | VAF 36/395 reads (9%) | called by muse, mutect2
- DNAH2 | c.1617C>A p.P539= | Silent (SNP) | VAF 41/116 reads (35%) | called by muse, mutect2, varscan2
- DPF1 | c.210G>A p.S70= | Silent (SNP) | VAF 22/314 reads (7%) | called by muse, mutect2
- DYNC2H1 | c.5073T>C p.A1691= | Silent (SNP) | VAF 13/176 reads (7%) | called by muse, mutect2
- EFCC1 | c.1233G>A p.P411= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as rs1000426425; called by muse, mutect2, varscan2
- EFNB2 | c.846C>T p.N282= | Silent (SNP) | VAF 79/199 reads (40%) | catalogued as rs113878095; called by muse, mutect2, varscan2
- EHD2 | c.1179C>T p.L393= | Silent (SNP) | VAF 94/232 reads (41%) | catalogued as rs146746938; called by muse, mutect2, varscan2
- EME1 | c.150A>C p.S50= | Silent (SNP) | VAF 90/190 reads (47%) | called by muse, mutect2, varscan2
- FAM102A | c.756C>A p.L252= (on ENST00000373095 / NM_001035254.3; = p.L110= on NM_203305.2) | Silent (SNP) | VAF 33/216 reads (15%) | called by muse, mutect2, varscan2
- FAM171A1 | c.909G>A p.T303= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs140163568; called by muse, mutect2, varscan2
- FANCE | c.999C>T p.L333= | Silent (SNP) | VAF 75/439 reads (17%) | catalogued as rs776082827; ClinVar: likely benign; called by muse, mutect2, varscan2
- GJA3 | c.510G>A p.L170= | Silent (SNP) | VAF 40/422 reads (9%) | called by muse, mutect2
- HCN1 | c.195C>T p.G65= | Silent (SNP) | VAF 27/212 reads (13%) | called by muse, varscan2
- IRX2 | c.558C>T p.S186= | Silent (SNP) | VAF 96/265 reads (36%) | called by muse, mutect2, varscan2
- JCHAIN | c.342T>C p.C114= | Silent (SNP) | VAF 16/332 reads (5%) | called by muse, mutect2
- KHDC4 | c.1152G>A p.V384= | Silent (SNP) | VAF 21/236 reads (9%) | called by muse, mutect2
- KRT31 | c.897G>A p.T299= | Silent (SNP) | VAF 14/210 reads (7%) | catalogued as rs576563180; called by muse, mutect2
- KRT5 | c.1704C>T p.G568= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as rs200589093; called by muse, mutect2, varscan2
- KTI12 | c.303G>A p.P101= | Silent (SNP) | VAF 56/131 reads (43%) | catalogued as rs1296663253; called by muse, mutect2, varscan2
- LAMA2 | c.1248C>T p.C416= | Silent (SNP) | VAF 22/237 reads (9%) | catalogued as rs371944692; ClinVar: likely benign; called by muse, mutect2
- LRRC59 | c.774T>G p.G258= | Silent (SNP) | VAF 14/323 reads (4%) | called by muse, mutect2
- LRRC7 | c.1863T>C p.V621= (on ENST00000651989 / NM_001370785.2; = p.V588= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 25/258 reads (10%) | called by muse, mutect2
- LYSMD4 | c.744C>T p.T248= (on ENST00000409796 / NM_001284417.2; = p.T249= on NM_152449.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 112/304 reads (37%) | called by muse, mutect2, varscan2
- MAF | c.141C>T p.G47= | Silent (SNP) | VAF 18/310 reads (6%) | called by muse, mutect2
- MUC5B | c.13188C>A p.T4396= | Silent (SNP) | VAF 32/453 reads (7%) | called by muse, mutect2
- MYBBP1A | c.3984C>A p.P1328= | Silent (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- MYO3A | c.4725T>C p.N1575= | Silent (SNP) | VAF 10/232 reads (4%) | called by muse, mutect2
- NCBP2L | c.375C>T p.R125= | Silent (SNP) | VAF 21/310 reads (7%) | catalogued as rs773993102, COSV64943883; called by muse, mutect2
- NINL | c.805C>T p.L269= | Silent (SNP) | VAF 46/137 reads (34%) | called by muse, mutect2, varscan2
- NOTCH1 | c.2754C>T p.N918= | Silent (SNP) | VAF 92/224 reads (41%) | catalogued as rs373787791; called by muse, mutect2, varscan2
- NT5DC4 | c.36G>A p.A12= | Silent (SNP) | VAF 29/227 reads (13%) | catalogued as rs572356087; called by muse, mutect2, varscan2
- OBSCN | c.21711G>A p.Q7237= | Silent (SNP) | VAF 57/440 reads (13%) | catalogued as rs1415819241; called by muse, mutect2, varscan2
- OR51F2 | c.120C>T p.A40= | Silent (SNP) | VAF 35/65 reads (54%) | catalogued as rs747026783, COSV59065505; called by muse, mutect2, varscan2
- OSBP2 | c.2139C>T p.C713= | Silent (SNP) | VAF 22/293 reads (8%) | called by muse, mutect2
- PAGE1 | c.228A>G p.G76= | Silent (SNP) | VAF 19/143 reads (13%) | called by muse, mutect2, varscan2
- PAPPA | c.2715T>C p.N905= | Silent (SNP) | VAF 85/193 reads (44%) | catalogued as rs1402644768; called by muse, mutect2, varscan2
- PARS2 | c.1254C>T p.I418= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as rs1057522093, COSV64884078; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHB11 | c.2220C>T p.S740= | Silent (SNP) | VAF 117/300 reads (39%) | catalogued as rs782119531, COSV100697129, COSV61313165; called by muse, mutect2, varscan2
- PLCH1 | c.3612T>C p.D1204= (on ENST00000340059 / NM_001130960.2; = p.D1196= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/175 reads (15%) | called by muse, mutect2, varscan2
- PLEC | c.4545G>A p.A1515= (on ENST00000322810 / NM_201380.4; = p.A1405= on NM_000445.5) | Silent (SNP) | VAF 28/402 reads (7%) | catalogued as rs558224639; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- PNCK | c.366C>T p.G122= (on ENST00000340888 / NM_001366975.1; = p.G205= on NM_001039582.3) | Silent (SNP) | VAF 46/138 reads (33%) | catalogued as rs1486958430; called by muse, mutect2, varscan2
- POLG | c.1101T>C p.P367= | Silent (SNP) | VAF 14/384 reads (4%) | called by muse, mutect2
- PREP | c.1905G>A p.A635= (on ENST00000369110; = p.A701= on NM_002726.5) | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as rs554023510, COSV64871801; called by muse, mutect2, varscan2
- PTPRA | c.2244C>T p.V748= | Silent (SNP) | VAF 20/167 reads (12%) | called by muse, mutect2, varscan2
- RFPL4A | c.552C>T p.H184= | Silent (SNP) | VAF 250/725 reads (34%) | catalogued as rs550767660; called by muse, mutect2, varscan2
- RP1 | c.5493T>C p.H1831= | Silent (SNP) | VAF 18/322 reads (6%) | called by muse, mutect2
- S1PR1 | c.753G>A p.S251= | Silent (SNP) | VAF 77/207 reads (37%) | catalogued as COSV59514567; called by muse, mutect2, varscan2
- SALL3 | c.2646C>T p.A882= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as rs936883345; called by muse, mutect2, varscan2
- SAP130 | c.1041A>G p.L347= | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as rs1169243564; called by muse, mutect2, varscan2
- SBF1 | c.1218C>T p.G406= | Silent (SNP) | VAF 70/187 reads (37%) | catalogued as rs1387540259; called by muse, mutect2, varscan2
- SCN8A | c.4962C>T p.I1654= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as rs766702527; ClinVar: likely benign; called by muse, mutect2, varscan2
- SH3D19 | c.1860C>T p.F620= | Silent (SNP) | VAF 21/252 reads (8%) | catalogued as COSV100456026; called by muse, mutect2
- SHANK2 | c.3591C>T p.G1197= | Silent (SNP) | VAF 18/458 reads (4%) | called by muse, mutect2
- SKIDA1 | c.1473C>T p.A491= | Silent (SNP) | VAF 11/147 reads (7%) | catalogued as COSV71610907; called by muse, mutect2
- SLC12A5 | c.516C>T p.S172= (on ENST00000454036 / NM_001134771.2; = p.S149= on NM_020708.5) | Silent (SNP) | VAF 11/163 reads (7%) | catalogued as rs1467052207; called by muse, mutect2
- SLC18B1 | c.948C>T p.C316= | Silent (SNP) | VAF 35/114 reads (31%) | called by muse, mutect2, varscan2
- SLC4A7 | c.2931A>C p.T977= | Silent (SNP) | VAF 32/299 reads (11%) | called by muse, mutect2, varscan2
- SLC9B1 | c.900G>A p.L300= | Silent (SNP) | VAF 7/167 reads (4%) | called by muse, mutect2
- SNX18 | c.138C>T p.G46= | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as COSV57987366; called by muse, mutect2, varscan2
- SUMO4 | c.279T>A p.G93= | Silent (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.1809C>T p.P603= | Silent (SNP) | VAF 17/204 reads (8%) | catalogued as rs968574559; called by muse, mutect2
- SYCP2L | c.2331G>T p.L777= | Silent (SNP) | VAF 9/196 reads (5%) | called by muse, mutect2
- TBR1 | c.1731C>T p.G577= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs765786081; called by muse, mutect2, varscan2
- TEPSIN | c.1494C>T p.R498= | Silent (SNP) | VAF 16/226 reads (7%) | catalogued as rs147469175; called by muse, mutect2
- TEX29 | c.78T>C p.Y26= | Silent (SNP) | VAF 68/193 reads (35%) | called by muse, mutect2
- TNRC6A | c.4293C>T p.S1431= | Silent (SNP) | VAF 47/139 reads (34%) | catalogued as rs574804099, COSV59363229; called by muse, mutect2, varscan2
- TNRC6B | c.663C>A p.A221= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV57309547; called by muse, mutect2
- TRAK2 | c.2103C>T p.S701= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as rs1356832535; called by muse, mutect2, varscan2
- TREX2 | c.678G>A p.E226= (on ENST00000334497; = p.E183= on NM_080701.3) | Silent (SNP) | VAF 14/220 reads (6%) | catalogued as COSV57847855; called by muse, mutect2
- TTN | c.88050A>G p.A29350= (on ENST00000591111; = p.A21926= on NM_003319.4) | Silent (SNP) | VAF 32/367 reads (9%) | called by muse, mutect2
- TTN | c.70821C>T p.S23607= (on ENST00000591111; = p.S16183= on NM_003319.4) | Silent (SNP) | VAF 29/200 reads (15%) | catalogued as rs786205379, COSV60386482; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.5742G>A p.A1914= (on ENST00000591111; = p.A1868= on NM_003319.4) | Silent (SNP) | VAF 92/219 reads (42%) | catalogued as rs368719553; ClinVar: likely benign; called by muse, varscan2
- UBA1 | c.2118C>T p.C706= | Silent (SNP) | VAF 16/318 reads (5%) | catalogued as rs782597501, COSV100256065; called by muse, mutect2
- UIMC1 | c.639C>T p.N213= | Silent (SNP) | VAF 15/129 reads (12%) | catalogued as rs138261725; called by muse, mutect2, varscan2
- UNC80 | c.8520C>T p.I2840= | Silent (SNP) | VAF 127/309 reads (41%) | catalogued as rs779342576, COSV55894893; called by muse, mutect2, varscan2
- WDR17 | c.2946C>T p.R982= | Silent (SNP) | VAF 79/222 reads (36%) | catalogued as rs146440894; called by muse, mutect2, varscan2
- WWC3 | c.3012C>T p.G1004= | Silent (SNP) | VAF 15/242 reads (6%) | called by muse, mutect2
- ZBTB22 | c.315T>C p.F105= | Silent (SNP) | VAF 43/298 reads (14%) | called by muse, mutect2, varscan2
- ZNF213 | c.1353C>T p.H451= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs545882716, COSV67727730; called by mutect2, varscan2
- ZNF521 | c.1842G>A p.Q614= | Silent (SNP) | VAF 11/132 reads (8%) | catalogued as COSV64125805; called by muse, mutect2
- ZNF587 | c.1623T>C p.I541= | Silent (SNP) | VAF 90/241 reads (37%) | called by muse, mutect2, varscan2
- ZNF658 | c.834C>T p.S278= | Silent (SNP) | VAF 123/346 reads (36%) | called by muse, mutect2, varscan2
- ZNF696 | c.508C>A p.R170= | Silent (SNP) | VAF 12/65 reads (18%) | called by mutect2, varscan2
- ZNF837 | c.1371C>T p.R457= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as rs773388390; called by muse, mutect2
- ZSWIM9 | c.1140C>T p.N380= | Silent (SNP) | VAF 28/382 reads (7%) | called by muse, mutect2
- AC092675.1 | n.445C>G | RNA (SNP) | VAF 9/202 reads (4%) | called by muse, mutect2
- AC105942.1 | n.1189del | RNA (DEL) | VAF 16/164 reads (10%) | called by mutect2, pindel
- AIPL1 | c.785-15C>T | Intron (SNP) | VAF 37/101 reads (37%) | catalogued as COSV100006024; called by muse, mutect2, varscan2
- BRCA1 | c.*1287dup | 3'UTR (INS) | VAF 72/184 reads (39%) | catalogued as rs755411080; called by mutect2, varscan2
- C10orf67 | c.206+637T>G | Intron (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2
- CCDC12 | c.244+142T>C | Intron (SNP) | VAF 11/156 reads (7%) | catalogued as rs1559547623; called by muse, mutect2
- CLEC12A | c.642-759G>A | Intron (SNP) | VAF 6/10 reads (60%) | catalogued as rs982549031, COSV58560733; called by muse, mutect2
- CSTB | c.67-32T>C | Intron (SNP) | VAF 24/303 reads (8%) | called by muse, mutect2
- CYB5R2 | chr11:7674348 T>C | 5'Flank (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- DMTN | c.*855del | 3'UTR (DEL) | VAF 10/35 reads (29%) | catalogued as rs1300307029; called by mutect2, pindel, varscan2
- DOCK8 | chr9:214588 G>T | 5'Flank (SNP) | VAF 11/286 reads (4%) | called by muse, mutect2
- FER1L4 | n.4411T>C | RNA (SNP) | VAF 11/196 reads (6%) | called by muse, mutect2
- FOXP2 | c.*709G>A | 3'UTR (SNP) | VAF 12/302 reads (4%) | catalogued as rs975419977; called by muse, mutect2
- GABRA1 | c.560-18del | Intron (DEL) | VAF 16/176 reads (9%) | called by mutect2, pindel
- GSN-AS1 | chr9:121286129 del C | 5'Flank (DEL) | VAF 55/180 reads (31%) | catalogued as rs1289822760; called by mutect2, pindel, varscan2
- H2AZ1 | c.3+40dup | Intron (INS) | VAF 13/108 reads (12%) | called by mutect2, pindel
- HLA-F | c.335-92A>G | Intron (SNP) | VAF 9/156 reads (6%) | called by muse, mutect2
- INTS1 | c.*21del | 3'UTR (DEL) | VAF 35/84 reads (42%) | called by mutect2, pindel, varscan2
- ITFG2 | c.*54del | 3'UTR (DEL) | VAF 53/175 reads (30%) | catalogued as rs1565419542; called by mutect2, pindel, varscan2
- KNOP1P1 | n.249del | RNA (DEL) | VAF 12/23 reads (52%) | catalogued as rs762636138; called by mutect2, varscan2
- LINC01551 | n.1254+18520G>A | Intron (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2
- LRSAM1 | c.252+19A>G | Intron (SNP) | VAF 18/230 reads (8%) | catalogued as COSV55939906; called by muse, mutect2
- MCOLN1 | c.681-50C>T | Intron (SNP) | VAF 11/92 reads (12%) | catalogued as rs373696018; called by muse, mutect2, varscan2
- MIDEAS | c.2162+46T>C | Intron (SNP) | VAF 12/191 reads (6%) | called by muse, mutect2
- MON1A | c.278+15A>G | Intron (SNP) | VAF 35/386 reads (9%) | called by muse, mutect2
- MUC20 | chr3:195720951 A>G | 5'Flank (SNP) | VAF 8/222 reads (4%) | catalogued as rs1192985250; called by muse, mutect2
- NAA60 | c.*5G>A | 3'UTR (SNP) | VAF 12/302 reads (4%) | catalogued as rs1012467395; called by muse, mutect2
- NAMPTP1 | n.772G>A | RNA (SNP) | VAF 79/268 reads (29%) | catalogued as rs775741679; called by muse, mutect2, varscan2
- PIK3R6 | c.-104C>T | 5'UTR (SNP) | VAF 21/48 reads (44%) | catalogued as rs1239266039; called by muse, mutect2, varscan2
- PLP1 | c.191+39del | Intron (DEL) | VAF 44/147 reads (30%) | catalogued as rs762304113; called by mutect2, varscan2
- PLPPR2 | c.*261C>T | 3'UTR (SNP) | VAF 18/277 reads (6%) | catalogued as COSV52261616; called by muse, mutect2
- POPDC2 | c.1009+23G>A | Intron (SNP) | VAF 15/149 reads (10%) | called by muse, mutect2
- RIMS2 | c.2196+31del | Intron (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel, varscan2
- RNF32 | chr7:156640428 C>T | 5'Flank (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.1280-3843G>A | Intron (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- SCLY | c.802-176C>T | Intron (SNP) | VAF 31/101 reads (31%) | catalogued as rs763038417; called by muse, mutect2, varscan2
- SPATA31C1 | n.3295G>A | RNA (SNP) | VAF 126/344 reads (37%) | catalogued as rs755564536; called by muse, mutect2, varscan2
- ST7 | c.151+3029del | Intron (DEL) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- SYN1 | c.-2C>T | 5'UTR (SNP) | VAF 30/245 reads (12%) | called by muse, mutect2, varscan2
- TBX5 | c.*109dup | 3'UTR (INS) | VAF 47/176 reads (27%) | called by pindel, varscan2
- TCF20 | c.*6del | 3'UTR (DEL) | VAF 58/164 reads (35%) | catalogued as COSV59497394; called by mutect2, varscan2
- TCF3 | c.1586+13C>A | Intron (SNP) | VAF 45/97 reads (46%) | catalogued as COSV99514517; called by muse, mutect2, varscan2
- TNFRSF14 | c.305-122G>A | Intron (SNP) | VAF 24/211 reads (11%) | called by muse, mutect2, varscan2
- TP53 | c.993+256_993+257del | Intron (DEL) | VAF 90/299 reads (30%) | called by mutect2, pindel, varscan2
- VGLL3 | c.937+5523G>A | Intron (SNP) | VAF 15/33 reads (45%) | catalogued as rs753566223; called by muse, mutect2, varscan2
- ZNF606 | c.-52+350G>A | Intron (SNP) | VAF 12/109 reads (11%) | catalogued as rs919167381; called by muse, mutect2, varscan2
